Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16B-01A (Primary Tumor).

[page 1 of 2]
Adenocarcinoma, Endometrioid, NOS

838013 12/9/10

Surgical Pathology Site Code: Endometrium C54.1
TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 B1 B2 B3 B4
B5 B6 B7 B8
B9 C1 C2 C3 C4 C5 C6 D1 E1 F1 G1 H1 I1
Uterus, right ovary (2.3 x 1.0 x 0.6 cm) with 6.5 cm
segment of
right fallopian tube, and left ovary (2.4 x 1.0 x 0.7 cm)
with 6.2
cm segment of left fallopian tube together weighing 135.0
grams,
separately submitted right and left pelvic lymph nodes,
separately
submitted right and left para-aortic lymph nodes above and
below the
inferior mesenteric artery, right gonadal vessels (7.2 cm
in length)
and left gonadal vessels (1.3 x 0.8 x 0.5 cm).

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; total
abdominal

hysterectomy and bilateral salpingo-oophorectomy:

Endometrioid

adenocarcinoma, FIGO II (of III) forming a mass (3.2 x 2.7
x 1.9 cm)

in the upper endometrial cavity. The tumor invades into
the

myometrium to a maximum depth of 1.3 cm (total myometrial
thickness,

2.3 cm). Lymphatic vascular invasion is not identified.

The cervix

shows acute and chronic cervicitis with erosion.

Ovaries and fallopian tubes, right and left salpingo-
oophorectomies:

No diagnostic abnormalities.

Lymph nodes, right pelvic, excision: Multiple (2 internal
iliac, 2

common iliac, 1 external iliac and 2 obturator) right
pelvic lymph

nodes are negative for tumor.

[page 2 of 2]
Lymph nodes, left pelvic, excision: Multiple (5 common iliac, 4 external iliac and 2 obturator) left pelvic lymph nodes are negative for tumor. A specimen submitted as "left internal iliac pelvic lymph nodes" contained no nodal tissue.

Lymph nodes, right and left para-aortic, excision: Multiple (3 left above IMA, 4 left below IMA, 2 right above IMA, and 3 right below IMA) para-aortic lymph nodes are negative for tumor.

Gonadal vessels, excision: Left and right gonadal vessels are negative for tumor.

Source: NCI Genomic Data Commons file 7f86fd0e-4ee8-476b-a70d-68b5f19ea7d0 (TCGA-D1-A16B.1B9ED459-4046-4DD9-ABA5-E815A90601A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).